Somatic mutation profile of tumor specimen MMRF_1389_2_BM_CD138pos (aliquot MMRF_1389_2_BM_CD138pos_T1_KBS5U_L05851) from MMRF case MMRF_1389, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.9 years (18,960 days).
Specimen MMRF_1389_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a99bf478-a0ba-4f2b-a761-c5713621530f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1389_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1389_2_PB_WBC_C2_KBS5U_L05826; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7270b0d-6efe-47f9-8cbe-37502bb6b68c

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAB20 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2
- MCF2L | chr13:113099465 C>T | 3'Flank (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- MYMX | c.*91G>A | 3'UTR (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
